Somatic mutation profile of tumor specimen ALCH-B2RE-TTP1-A (aliquot ALCH-B2RE-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B2RE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.3 years (21,312 days).
Specimen ALCH-B2RE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0aeac57e-3fce-465d-8e85-5a7a7e35a9f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2RE-NB1-A (Blood Derived Normal), aliquot ALCH-B2RE-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03e5bb1b-5332-47ba-a78a-eabf8d3ddffd

The open-access MAF lists 48 somatic variants for this specimen: 33 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 11, Splice Region 2, Intron 2, Nonsense Mutation 2, RNA 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 57/389 reads (15%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- CES1 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 116/1238 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs372957576, COSV100828872; called by muse, mutect2
- CP | c.2398G>A p.A800T | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs774236869; called by muse, mutect2, varscan2
- GJB1 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 60/269 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.284); catalogued as rs763991026, CM081654; called by muse, mutect2, varscan2
- GRIN2A | c.251C>T p.T84M | Missense Mutation (SNP) | VAF 37/443 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1354238435, COSV58046734; called by muse, mutect2
- GTF3C5 | c.573G>A p.R191= | Splice Region (SNP) | VAF 13/159 reads (8%) | catalogued as rs768532181; called by muse, mutect2
- IQCJ-SCHIP1 | c.1508T>C p.L503P (on ENST00000485419 / NM_001197113.1; = p.L427P on NM_014575.3) | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100540544; called by muse, mutect2, varscan2
- MAGED1 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 23/395 reads (6%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.106); catalogued as rs201938318, COSV58515142; called by muse, mutect2
- MAP1A | c.986C>T p.T329M | Missense Mutation (SNP) | VAF 45/406 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as rs139538952; called by muse, mutect2, varscan2
- MYO7B | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765756611; called by muse, mutect2
- PAN3 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV56702126; called by muse, mutect2, varscan2
- PLEK | c.107A>G p.Y36C | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs201401748; called by muse, mutect2, varscan2
- PTPRD | c.53C>T p.T18M | Missense Mutation (SNP) | VAF 36/486 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs376714429; called by muse, mutect2
- RBMX2 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 19/238 reads (8%) | catalogued as COSV100564759, COSV59729841; called by muse, mutect2
- YY1 | c.1115C>G p.T372R | Missense Mutation (SNP) | VAF 96/433 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs386834266, COSV51761462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZDBF2 | c.6244C>T p.H2082Y | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); catalogued as COSV65625143; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4700C>A p.T1567N | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.915); called by muse, mutect2
- CDH23 | c.215A>T p.E72V | Missense Mutation (SNP) | VAF 37/272 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- CELSR3 | c.5500T>G p.S1834A | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CNTNAP3 | c.2666C>T p.S889F | Missense Mutation (SNP) | VAF 15/493 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.481); called by muse, mutect2
- CP | c.2399C>A p.A800D | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DISP3 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- EPB41L1 | c.1292T>G p.L431R | Missense Mutation (SNP) | VAF 90/479 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- FASTKD2 | c.1712C>T p.S571L | Missense Mutation (SNP) | VAF 41/441 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2
- HAS1 | c.1192C>T p.H398Y | Missense Mutation (SNP) | VAF 29/295 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- KMT2D | c.3274A>C p.S1092R | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- MAGEB6 | c.574A>G p.K192E | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.08); called by muse, mutect2
- MMP16 | c.1646T>C p.V549A | Missense Mutation (SNP) | VAF 77/379 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NRK | c.1296G>T p.Q432H | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- OR1L3 | c.22A>G p.R8G | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4M1 | c.286G>T p.G96* | Nonsense Mutation (SNP) | VAF 26/634 reads (4%) | called by muse, mutect2
- SLC6A7 | c.1335G>A p.G445= | Splice Region (SNP) | VAF 15/196 reads (8%) | called by muse, mutect2
- TICRR | c.2713A>G p.T905A | Missense Mutation (SNP) | VAF 41/240 reads (17%) | SIFT tolerated (0.91); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ADARB1 | c.759C>T p.S253= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as rs200567642, COSV62348267; called by muse, mutect2
- AVPR1A | c.36G>A p.S12= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs1414515126, COSV54547254; called by muse, mutect2
- BICRAL | c.3201C>T p.S1067= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as COSV58405750; called by muse, varscan2
- MAP1B | c.3288C>T p.S1096= | Silent (SNP) | VAF 20/146 reads (14%) | catalogued as rs768215895, COSV57101776; called by muse, mutect2, varscan2
- MYH7 | c.2301C>T p.A767= | Silent (SNP) | VAF 28/444 reads (6%) | catalogued as rs768380939, COSV62523319; ClinVar: likely benign; called by muse, mutect2
- PLCH2 | c.993G>A p.P331= | Silent (SNP) | VAF 99/365 reads (27%) | catalogued as rs371798111; called by muse, mutect2, varscan2
- SDS | c.507C>T p.G169= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs779714832, COSV99980937; called by muse, mutect2, varscan2
- SEPTIN4 | c.1359C>T p.I453= | Silent (SNP) | VAF 28/154 reads (18%) | called by muse, varscan2
- SOWAHB | c.1074G>T p.S358= | Silent (SNP) | VAF 32/172 reads (19%) | catalogued as rs376259300; called by muse, mutect2, varscan2
- TGM6 | c.429C>T p.D143= | Silent (SNP) | VAF 42/390 reads (11%) | catalogued as rs1349171895, COSV99173012; called by muse, mutect2
- USP28 | c.2337C>A p.I779= | Silent (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503064 G>A | 5'Flank (SNP) | VAF 9/51 reads (18%) | catalogued as rs755452277; called by muse, mutect2, varscan2
- CCDC162P | n.6275G>A | RNA (SNP) | VAF 27/191 reads (14%) | catalogued as rs1191335281; called by muse, mutect2, varscan2
- FTCD | c.368-9C>G | Intron (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- NCBP1 | c.2259+77A>G | Intron (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
